Somatic mutation profile of tumor specimen TCGA-BG-A0M3-01A (aliquot TCGA-BG-A0M3-01A-11W-A10C-09) from TCGA case TCGA-BG-A0M3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 74.4 years (27,183 days).
Specimen TCGA-BG-A0M3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ff3dd55-8397-4bee-9e4e-32c628bdf63c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0M3-10A (Blood Derived Normal), aliquot TCGA-BG-A0M3-10A-01D-A127-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9d23e03-a7e4-45af-8dae-feb35055bf62

The open-access MAF lists 69 somatic variants for this specimen: 56 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 44, Silent 13, Nonsense Mutation 3, Frame Shift Ins 3, Frame Shift Del 2, Splice Site 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.4003C>T p.R1335* | Nonsense Mutation (SNP) | VAF 64/116 reads (55%) | hotspot (GDC flag); catalogued as rs387906846, CM122485, COSV61371872; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 34/88 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 84/140 reads (60%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PIK3R1 | c.1710dup p.I571Yfs*31 (on ENST00000521381 / NM_181523.3; = p.I301Yfs*31 on NM_181504.4) | Frame Shift Ins (INS) | VAF 139/379 reads (37%) | catalogued as rs1561299903, COSV57129116; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.141del p.N48Tfs*6 | Frame Shift Del (DEL) | VAF 580/1157 reads (50%) | catalogued as rs1114167670, COSV100909326, COSV64292806; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAMTS17 | c.1458C>A p.F486L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.38); catalogued as COSV51473742; called by muse, mutect2, varscan2
- ADCY8 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.101); catalogued as rs202036797, COSV53897297; called by muse, mutect2, varscan2
- APOBEC4 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 208/355 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as rs779521158, COSV58016901; called by muse, mutect2, varscan2
- ATP6V0A4 | c.639+2T>C p.X213_splice | Splice Site (SNP) | VAF 57/221 reads (26%) | catalogued as COSV59472706; called by muse, mutect2, varscan2
- BIRC6 | c.5588G>A p.R1863H | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs776988218, COSV70195731; called by muse, mutect2, varscan2
- CAB39L | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs149022536, COSV61713679; called by muse, mutect2, varscan2
- CACNA1B | c.1068G>A p.S356= | Splice Region (SNP) | VAF 76/177 reads (43%) | catalogued as rs1424578865, COSV53114872; called by muse, mutect2, varscan2
- CD28 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 91/177 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1371617402, COSV60730055; called by muse, mutect2, varscan2
- CDR2 | c.242C>G p.A81G | Missense Mutation (SNP) | VAF 187/443 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV51675263; called by muse, mutect2, varscan2
- CRISP3 | c.457G>T p.D153Y (on ENST00000371159 / NM_001368123.1; = p.D135Y on NM_006061.4) | Missense Mutation (SNP) | VAF 127/300 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.317); catalogued as COSV53819126, COSV53819602; called by muse, mutect2
- CTNNB1 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 233/510 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs755119590, COSV62690545, COSV62698719; called by muse, mutect2, varscan2
- DACH2 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 101/225 reads (45%) | SIFT tolerated (0.87); PolyPhen benign (0.109); catalogued as rs754406197, COSV64162340; called by muse, mutect2, varscan2
- EIF2AK1 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV52236320; called by muse, mutect2, varscan2
- ENHO | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.101); catalogued as rs1016540218, COSV54278916; called by muse, mutect2, varscan2
- EPM2AIP1 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.244); catalogued as COSV51614592; called by mutect2, varscan2
- EPS8 | c.2140C>T p.Q714* | Nonsense Mutation (SNP) | VAF 182/398 reads (46%) | catalogued as COSV55527819; called by muse, mutect2, varscan2
- GATAD2A | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1296839596, COSV53066981, COSV53075761; called by muse, mutect2, varscan2
- GPRASP1 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 98/187 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as COSV64354846; called by muse, mutect2, varscan2
- INSRR | c.2450G>T p.G817V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV63871008; called by muse, mutect2, varscan2
- JCHAIN | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV54658171; called by muse, mutect2, varscan2
- KAZN | c.2041C>A p.P681T | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs776931028, COSV65714899; called by muse, mutect2, varscan2
- KCNA6 | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1348444167, COSV54974145, COSV54975714, COSV99768309; called by muse, mutect2, varscan2
- KRTAP19-2 | c.28G>A p.G10S | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV61854531; called by muse, mutect2, varscan2
- LRRC30 | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.143); catalogued as COSV67301315; called by muse, mutect2, varscan2
- MAP3K15 | c.1746A>G p.I582M | Missense Mutation (SNP) | VAF 147/365 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58826205; called by muse, mutect2, varscan2
- MAP4K5 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 122/261 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs1260633145, COSV50152703, COSV50160172; called by muse, mutect2, varscan2
- MARCHF11 | c.900T>G p.H300Q | Missense Mutation (SNP) | VAF 75/250 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60126223; called by muse, mutect2, varscan2
- NRG3 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs764611896, COSV64545820, COSV64548799; called by muse, mutect2, varscan2
- OGFOD3 | c.297G>T p.R99S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV57339258; called by muse, mutect2, varscan2
- PHF20L1 | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 174/378 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV55189025; called by muse, mutect2, varscan2
- PIGQ | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.644); catalogued as rs752737257, COSV50312258; called by muse, mutect2, varscan2
- PIK3R1 | c.1630A>T p.R544* (on ENST00000521381 / NM_181523.3; = p.R274* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 127/294 reads (43%) | catalogued as COSV57124298; called by muse, mutect2, varscan2
- PROS1 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV67774343; called by muse, mutect2, varscan2
- RBBP7 | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 154/365 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV66300343; called by muse, mutect2, varscan2
- RSPH9 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV64664139; called by muse, mutect2, varscan2
- RXFP1 | c.1435T>G p.W479G | Missense Mutation (SNP) | VAF 135/287 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV57046942; called by muse, mutect2, varscan2
- SEC13 | c.307G>A p.D103N (on ENST00000350697 / NM_183352.3; = p.D106N on NM_030673.4) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs1047781015, COSV61601260; called by muse, mutect2, varscan2
- SECISBP2L | c.2855A>C p.E952A (on ENST00000559471 / NM_001193489.2; = p.E907A on NM_014701.4) | Missense Mutation (SNP) | VAF 115/309 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55932793; called by muse, mutect2, varscan2
- SH3BGRL | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 163/374 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV64619767; called by muse, mutect2, varscan2
- SLC25A12 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 118/249 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1034277307, COSV55531609; called by muse, mutect2, varscan2
- SPOP | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 97/246 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV61652768; called by muse, mutect2, varscan2
- TREM2 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 87/216 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); catalogued as COSV100632633, COSV58293842, COSV58295576; called by muse, mutect2, varscan2
- USF2 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV55885274; called by muse, mutect2, varscan2
- VWA3A | c.1696G>A p.V566M | Missense Mutation (SNP) | VAF 142/284 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs756509297, COSV55388135; called by muse, mutect2, varscan2
- WASHC4 | c.3335G>A p.R1112Q | Missense Mutation (SNP) | VAF 105/246 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59888563; called by muse, mutect2, varscan2
- ADSS2 | c.681del p.K228Nfs*4 | Frame Shift Del (DEL) | VAF 158/554 reads (29%) | called by mutect2, pindel, varscan2
- AMPD3 | c.1430+2dup p.X477_splice (on ENST00000396553 / NM_001025389.2; = p.X486_splice on NM_000480.3) | Splice Site (INS) | VAF 29/71 reads (41%) | called by mutect2, pindel, varscan2
- CDKAL1 | c.1714_1719del p.A572_F573del | In Frame Del (DEL) | VAF 143/418 reads (34%) | called by mutect2, pindel, varscan2
- LHX1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PTEN | c.954dup p.T319Yfs*6 | Frame Shift Ins (INS) | VAF 166/657 reads (25%) | called by mutect2, pindel, varscan2
- VCAN | c.4579dup p.T1527Nfs*2 | Frame Shift Ins (INS) | VAF 102/297 reads (34%) | called by mutect2, pindel, varscan2
- APLP2 | c.1890G>A p.E630= | Silent (SNP) | VAF 242/531 reads (46%) | catalogued as COSV53839065, COSV53842874; called by muse, mutect2, varscan2
- CCDC18 | c.3672T>C p.Y1224= (on ENST00000343253 / NM_001306076.1; = p.Y1225= on NM_206886.4) | Silent (SNP) | VAF 160/359 reads (45%) | catalogued as COSV58141471; called by muse, mutect2, varscan2
- CHD7 | c.7266G>A p.E2422= | Silent (SNP) | VAF 69/154 reads (45%) | catalogued as COSV71107367; called by muse, mutect2, varscan2
- FAM160A2 | c.1101C>G p.L367= | Silent (SNP) | VAF 115/275 reads (42%) | catalogued as COSV56409643, COSV56410733; called by muse, mutect2, varscan2
- GBP1 | c.1327C>T p.L443= | Silent (SNP) | VAF 141/332 reads (42%) | catalogued as COSV65082649; called by muse, mutect2, varscan2
- MFSD1 | c.136C>T p.L46= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs759982429, COSV51839197; called by muse, mutect2, varscan2
- PCDHB6 | c.2172G>A p.S724= | Silent (SNP) | VAF 43/89 reads (48%) | catalogued as COSV50690061; called by muse, mutect2, varscan2
- PREX2 | c.4494T>C p.C1498= | Silent (SNP) | VAF 59/133 reads (44%) | catalogued as COSV55752104; called by muse, mutect2, varscan2
- SERPINB3 | c.336G>A p.T112= | Silent (SNP) | VAF 205/518 reads (40%) | catalogued as rs1451314201, COSV52189902; called by muse, mutect2, varscan2
- SMIM21 | c.93C>T p.F31= | Silent (SNP) | VAF 163/369 reads (44%) | catalogued as COSV66894567; called by muse, mutect2, varscan2
- SPEG | c.7941G>A p.A2647= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs774420776, COSV56663560; called by muse, mutect2, varscan2
- SPIDR | c.1716C>G p.T572= | Silent (SNP) | VAF 129/327 reads (39%) | catalogued as COSV52370255; called by muse, mutect2, varscan2
- SUPT20HL2 | c.2394A>G p.Q798= | Silent (SNP) | VAF 47/110 reads (43%) | called by muse, mutect2, varscan2
